Surgical pathology report (de-identified scan), TCGA case TCGA-12-1602, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Duke, specimen TCGA-12-1602-01A (Primary Tumor).

[page 1 of 2]
Patient: [REDACTED]

AP Surgical Pathology: Additional Info [REDACTED] Acc# [REDACTED]

Surg Path

12-1602

CLINICAL HISTORY:

Brain tumor.

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received fresh for frozen section is a 4 x 3.5 x 2 cm aggregate of pink-tan soft tissue. Representative section has been frozen as AF1 and the frozen section remnant is submitted in block A1. Additional representative sections are submitted in blocks A2-6 with the remainder retained in formalin.

B. "Brain tissue", received fresh and placed in formalin is a 4 x 3 x 1.7 cm aggregate of pink-tan soft tissue. The specimen is serially sectioned with representative cross sections submitted in blocks B1-4, and the remainder is retained in formalin.

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1-high grade glioma [REDACTED]

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a malignant astrocytic neoplasm characterized by cytologic pleomorphism, mitotic figures, microvascular proliferation and necrosis.

DIAGNOSIS:

A. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

B. "BRAIN TISSUE" (CRANIOTOMY):

GLIOBLASTOMA (WHO GRADE IV).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

CHROMOSOME 7 CENTROMERE - POLYSOMY (62% OF TUMOR CELLS EXHIBIT POLYSOMY)

EGFR - POLYSOMY (62% OF TUMOR CELLS EXHIBIT POLYSOMY)

CHROMOSOME 10 CENTROMERE - CENTROMERE LOSS (52% OF TUMOR CELLS EXHIBIT LOSS)

PTEN - ALLELIC LOSS (73% OF TUMOR CELLS EXHIBIT LOSS)

9p21 - INTACT (NO LOSS)

CHROMOSOME 9 CENTROMERE - INTACT (NO LOSS)

[page 2 of 2]
4 OF 4 ABNORMAL MARKERS.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF [REDACTED] PATIENTS WITH GLIOBLASTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH 4 ABNORMAL MARKERS EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

12-1602

BOTH FISH AND IMMUNOHISTOCHEMISTRY FOR PTEN REVEAL SIMILAR FINDINGS INDICATIVE OF LOSS OF PTEN STATUS.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

ADDENDUM 2:

IMMUNOHISTOCHEMICAL LABELING INDEX OF TUMOR CELLS:

TISSUE TYPE: BRAIN TISSUE CONTAINING GLIOBLASTOMA (WHO GRADE IV; [REDACTED] BLOCK A6).

LEUCOCYTE COMMON ANTIGEN (LCA): 15% OF POSITIVE CELLS.

PROLIFERATION INDEX INTERPRETATION: HIGH PROLIFERATION INDEX (20% OF TUMOR CELLS EXHIBIT STAINING).

MGMT - NEGATIVE (3% OF TUMOR CELLS).

EGFR wt - POSITIVE (2+ IN 80% OF TUMOR CELLS)

EGFR vIII - NEGATIVE (0% OF TUMOR CELLS)

PTEN - LOSS (2+ IN 40% OF TUMOR CELLS)

S6 - POSITIVE (2+ IN 40% OF TUMOR CELLS)

AKT - NEGATIVE (2+ IN 20% OF TUMOR CELLS)

MAPK - POSITIVE (2+ IN 50% OF TUMOR CELLS)

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]
Electronically signed: [REDACTED]

Performed by: [REDACTED]

Ordering MD:
[REDACTED]

Source: NCI Genomic Data Commons file c0cf524d-ad70-4faa-b987-7e8c46688a9b (TCGA-12-1602.C1981720-4558-43B4-BD31-F420A9E34589.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).